Surgical pathology report (de-identified scan), TCGA case TCGA-CN-6018, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-6018-01A (Primary Tumor).

[page 1 of 6]
Pathology Report [REDACTED] **FINAL**

Report Type Pathology Report
Date of Event [REDACTED]
Sex [REDACTED]
Authored by [REDACTED]
Hosp/Group [REDACTED]
Record Status FINAL

FINAL DIAGNOSIS:

PART 1: MANDIBULAR MASS, LEFT, BIOPSY

INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA AND NECROTIC DEBRIS (see comment).

PART 2: MANDIBULAR MASS, LEFT #2, BIOPSY

INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA.

PART 3: PROXIMAL INFERIOR ALVEOLAR NERVE, SHAVE MARGIN, BIOPSY
NO TUMOR SEEN.

PART 4: LEFT FLOOR OF MOUTH, SHAVE MARGIN, BIOPSY

- A. SQUAMOUS MUCOSA WITH ACUTE AND CHRONIC INFLAMMATION.
- B. MINOR SALIVARY GLANDS WITH CHRONIC SIALADENITIS.
- C. NO TUMOR SEEN.

PART 5: LEFT BUCCAL SHAVE MARGIN, BIOPSY
NO TUMOR SEEN.

PART 6: LEFT GINGIVAL LABIAL SHAVE MARGIN, BIOPSY

- A. SQUAMOUS MUCOSA WITH ACUTE AND CHRONIC INFLAMMATION.
- B. MINOR SALIVARY GLAND WITH CHRONIC SIALADENITIS.
- C. NO TUMOR SEEN.

PART 7: BONE MARROW, SYMPHYSEAL MARGIN, BIOPSY
NO TUMOR SEEN.

PART 8: LEFT RETROMOLAR TRIGONE, BIOPSY

- A. SQUAMOUS MUCOSA WITH LYMPHOID AGGREGATE.
- B. MINOR SALIVARY GLANDS WITH CHRONIC SIALADENITIS.
- C. NO TUMOR SEEN.

PART 9: MANDIBLE AND SOFT TISSUE, LEFT COMPOSITE RESECTION

- A. ULCERATED INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED (4.5 CM) WITH INVASION INTO MANDIBULAR BONE.
- B. PERINEURAL INVASION IS PRESENT.
- C. NO ANGIOLYMPHATIC INVASION IS SEEN.
- D. ALL FINAL RESECTION MARGINS ARE FREE OF TUMOR (see also parts 3 through 8).
- E. METASTATIC SQUAMOUS CELL CARCINOMA IN ONE OF ONE LYMPH NODES (1/1). EXTRACAPSULAR EXTENSION IS PRESENT.
- F. SUBMANDIBULAR GLAND WITH CHRONIC SIALADENITIS AND ATROPHY.
- G. SEGMENT OF SKIN WITH SOLAR ELASTOSIS.
- H. PATHOLOGICAL STAGE pT4a N2b.

PART 10: LYMPH NODES, LEFT NECK LEVELS 2, 3 AND 4, DISSECTION

- A. METASTATIC SQUAMOUS CELL CARCINOMA IN ONE OF FOURTEEN LYMPH NODES (1/14).
- B. THE POSITIVE LYMPH NODE IS IN LEVEL 2.
- C. NO EXTRACAPSULAR EXTENSION IS SEEN.

PART 11: LYMPH NODES, RIGHT NECK LEVELS 1, 2 AND 3, DISSECTION

- A. FIVE LYMPH NODES FREE OF TUMOR (0/5).
- B. SUBMANDIBULAR GLAND WITH NO SIGNIFICANT PATHOLOGICAL CHANGE.

[page 2 of 6]
C. TAIL OF PAROTID WITH NO SIGNIFICANT PATHOLOGICAL CHANGE.

COMMENT:

Part 1: The squamous cell carcinoma is present only in the tissue not used for frozen section. The frozen section slides were reviewed and they do not contain tumor.

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received in eleven parts.

Part 1 is received fresh labeled with the patient's name, initials xxx and labeled "left mandibular mass." It consists of a 1.0 x 1.0 x 0.5 cm portion of soft, tan, friable tissue and bone. The specimen is received for intraoperative consultation and is resubmitted in cassette 1AFS. The remaining unfrozen portion is submitted in cassette 1DR.

Part 2 is received fresh labeled with the patient's name, initials xxx and labeled "left mandibular mass, Part 2." It consists of two fragments of soft, tan-pink tissue, 1.3 x 1.0 x 0.4 cm and 1.7 x 1.2 x 0.5 cm. The specimen is received for intraoperative consultation and is entirely resubmitted in cassette 2AFS.

Part 3 is received fresh labeled with the patient's name, initials xxx and labeled "proximal inferior alveolar nerve, inked true margin." It consists of a 0.3 x 0.2 x 0.3 cm portion of soft, tan tissue received for intraoperative consultation and is entirely resubmitted in cassette 3AFS.

Part 4 is received fresh labeled with the patient's name, initials xxx and labeled "left floor of mouth, suture anterior." It consists of a 4.0 x 0.4 x 0.3 cm portion of pink-tan, soft tissue. The specimen is inked black at the site of the suture and green at the opposite end. The specimen is received for intraoperative consultation and is entirely resubmitted in cassette 4AFS.

Part 5 is received fresh labeled with the patient's name, initials xxx and labeled "left buccal margin, suture anterior, inked new margin." It consists of a 1.5 x 0.7 x 0.5 cm portion of pink-tan, soft tissue. The specimen is inked black at the site of the suture. The specimen is received for intraoperative consultation and is entirely resubmitted in cassette 5AFS.

Part 6 is received fresh labeled with the patient's name, initials xxx and labeled "left gingival labial margin, suture anterior, inked new margin." It consists of a 2.0 x 0.6 x 0.4 cm portion of soft, pink-tan tissue. The site of the suture is inked black. The specimen is received for intraoperative consultation and is entirely resubmitted in cassette 6AF.

Part 7 is received fresh labeled with the patient's name, initials xxx and labeled "symphyseal marrow." It consists of fragments of tissue and bone, 0.3 x 0.3 x 0.3 cm in aggregate. The specimen is received for intraoperative consultation and is entirely resubmitted in cassette 7FS.

Part 8 is received fresh labeled with the patient's name, initials xxx and labeled "left retromolar trigone, inked new margin." It consists of a 1.5 x 0.5 x 0.4 cm portion of pink-tan, soft tissue. The specimen is received for

[page 3 of 6]
intraoperative consultation and is entirely resubmitted in cassette 8AFS.

Part 9 is received fresh labeled with the patient's name, initials xxx and labeled "left composite resection, suture anterior." It consists of a 10.0 x 6.0 x 5.0 cm left composite resection with a portion of mandible (ramus -- 5.0 x 3.4 x 0.6 cm, body -- 5.5 x 2.1 x 1.2 cm), submandibular gland (2.5 x 1.8 x 1.0 cm), skin ellipse (3.5 x 1.2 cm) and mucosa (6.0 x 5.0 cm). A suture marks the anterior mucosa.

Within the center of the mucosa is a 4.0 x 4.5 cm ulcerated lesion with white-tan, friable tissue in the ulcerated cavity extending to a depth of 1.5 cm. The mandible has a fracture in an area of gross tumor involvement between the ramus and the body. The attached skin ellipse is not grossly involved by tumor. The normal mucosa surrounding the tumor averages 0.5 cm in width. A 1.4 x 1.4 x 1.1 cm grossly positive lymph node is present in the deep soft tissues between the submandibular gland and the tumor. The lymph node metastasis is discretely separated from the tumor by 0.2 cm.

Ancillary studies:

Normal, primary tumor and metastatic tumor to a lymph node are banked for the head and neck tissue bank.

Digital photographs are taken.

Ink Code:

Black - Floor of mouth

Blue - lateral

Red - banking sites.

Representative sections are submitted as follows:

9ADR anterior mandibular bone shave margin

9BDR posterior mandibular bone shave margin

9CDR-9DDR representative sections of mandible at fracture and closest tumor

9E section of grossly positive lymph node in relationship to main tumor

9F representative section of tumor with normal mucosa

9G representative section of submandibular gland in relationship to tumor and positive lymph node (same lymph node as in 9E)

9H representative section of uninvolved skin in relationship to tumor.

Part 10 is received fresh labeled with the patient's name, initials xxx and

labeled "left neck, levels 2, 3, 4." It consists of a 14.0 x 6.0 x 1.0 cm

portion of yellow, lobulated adipose tissue with thin, pink fibrous strands.

Multiple possible lymph nodes are identified ranging from 0.3-2.0 cm in greatest dimension.

Representative sections are submitted as follows:

10A - one possible lymph node, bisected from level 2

10B possible lymph nodes from level 2

10C - possible lymph nodes from level 3

10D possible lymph nodes from level 4.

Part 11 is received fresh labeled with the patient's name, initials xxx and

labeled "right neck levels 1, 2 and 3." It consists of an 8.0 x 5.0 x 1.5 cm

portion of fibroadipose tissue with an attached submandibular gland (3.3 x 2.0

x 1.0 cm), and vessel (4.5 cm long x 0.3 cm in diameter). Multiple possible lymph nodes are identified.

Representative sections are submitted as follows:

11A representative section of submandibular gland

11B possible lymph nodes from level 1

11C possible lymph nodes from level 3

11D possible lymph nodes from level 2.

[page 4 of 6]
Dictated By: [REDACTED]

INTRAOPERATIVE CONSULTATION:

PART 1AFS: LEFT MANDIBULAR MASS (frozen section)

- A. BENIGN.
- B. NECROTIC DEBRIS WITH NUMEROUS BACTERIA AND FILAMENTOUS ORGANISMS (? ACTINOMYCES).
- C. RECOMMEND TISSUE CULTURE ([REDACTED])

PART 2AFS: LEFT MANDIBULAR MASS, PART 2 (frozen section)

- A. MALIGNANT.
- B. SQUAMOUS CELL CARCINOMA ([REDACTED]).

PART 3AFS: PROXIMAL INFERIOR ALVEOLAR NERVE, SHAVE MARGIN (frozen section)

- A. BENIGN.
- B. NO TUMOR ([REDACTED]).

PART 4AFS: LEFT FLOOR OF MOUTH, SHAVE MARGIN (frozen section)

- A. BENIGN.
- B. KERATOSIS WITH MILD ATYPIA ([REDACTED]).

PART 5AFS: LEFT BUCCAL SHAVE MARGIN (frozen section)

- A. BENIGN.
- B. NO TUMOR ([REDACTED]).

PART 6AFS: LEFT GINGIVAL LABIAL SHAVE MARGIN (frozen section)

- A. BENIGN.
- B. NO TUMOR ([REDACTED]).

PART 7AFS: SYMPHYSEAL MARROW MARGIN (frozen section)

- A. BENIGN.
- B. NO TUMOR ([REDACTED]).

PART 8AFS: LEFT RETROMOLAR TRIGONE SHAVE MARGIN (frozen section)

- A. BENIGN.
- B. NO TUMOR ([REDACTED]).

Dictated By: [REDACTED]

MICROSCOPIC:

[REDACTED]

The following statement applies to all immunohistochemistry, Insitu Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and Immunofluorescent Testing:

The testing was developed and its performance characteristics determined by the [REDACTED] Department of Pathology, as required by the CLIA [REDACTED] regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation ranges from a minimum of [REDACTED] to a maximum of [REDACTED] hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY UPPER AERODIGESTIVE TRACT AND SALIVARY GLAND TUMORS

SPECIMEN TYPE: Resection: Left composite resection

TUMOR SITE: Oral Cavity

[page 5 of 6]
TUMOR SIZE: Greatest dimension: 4.5 cm
HISTOLOGIC TYPE: Squamous cell carcinoma, conventional
HISTOLOGIC GRADE: G2
PRIMARY TUMOR (pT): pT4a
REGIONAL LYMPH NODES (pN): pN2b
Number of regional lymph nodes examined: 20
Number of regional lymph nodes involved: 2
Extra-capsular extension of nodal tumor: Present
DISTANT METASTASIS (pM): pMX
MARGINS: Margins uninvolved by tumor
VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):
Absent
PERINEURAL INVASION: Present
ADDITIONAL PATHOLOGIC FINDINGS: None identified

PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Oral cancer, left mandibular mass.

PROCEDURE: Left composite resection, bilateral neck dissection, flap graft.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMORADIATION THERAPY: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

OTHER DISEASES: Not answered.

CYTOGENETIC TESTING: Not answered.

Dictated By: [REDACTED]

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Left Mandibular Mass

Taken: [REDACTED]

Stain/cnt Block

H&E x 1 AFS

H&E x 1 [REDACTED]

Decal x 1 (none)

Part 2: Left Mandibular Mass Part 2

Taken: [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 3: Proximal Inferior Alveolar Nerve

Taken: [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 4: Left Floor of Mouth

Taken: [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 5: Left Buccal Margin

Taken: [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 6: Left Gingival Labial Margin

Taken: [REDACTED]

[page 6 of 6]
Stain/cnt Block

H&E x 1 AFS

Part 7: Symphyseal Marrow

Taken:

Stain/cnt Block

H&E x 1 AFS

Part 8: Left Retromolar Trigone

Taken:

Stain/cnt Block

H&E x 1 AFS

Part 9: Left Composite Resection

Taken:

Stain/cnt Block

H&E x 1 D

H&E x 1 E

H&E x 1 F

H&E x 1 G

H&E x 1 H

H&E x 1

H&E x 1

H&E x 1

Decal x 1 (none)

Part 10: Left neck Level 2-4

Taken:

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

Part 11: Right Neck Levels 1-3

Taken:

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

Source: NCI Genomic Data Commons file 2d469ed4-0b4c-4256-b5c6-f6c43177b56a (TCGA-CN-6018.FDAA5718-77F1-4357-9DB4-D655C7948D74.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).